Somatic mutation profile of tumor specimen TCGA-XP-A8T8-01A (aliquot TCGA-XP-A8T8-01A-11D-A36J-09) from TCGA case TCGA-XP-A8T8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 49.4 years (18,048 days).
Specimen TCGA-XP-A8T8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08e228fa-78a3-453a-9c17-79a2d4be8fb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XP-A8T8-10A (Blood Derived Normal), aliquot TCGA-XP-A8T8-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71b8176f-e29a-4e33-af12-776c889dbe4c

The open-access MAF lists 104 somatic variants for this specimen: 82 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 20, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 3, Splice Site 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK3 | c.5100G>C p.K1700N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1010741163, COSV51934834; called by muse, mutect2, varscan2
- CNOT6L | c.482A>G p.N161S (on ENST00000504123 / NM_001286790.2; = p.N156S on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.115); catalogued as rs754850131; called by muse, mutect2, varscan2
- COX18 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as rs1258977892, COSV55719833; called by muse, mutect2, varscan2
- DMXL1 | c.4094C>G p.S1365C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1285269329; called by muse, mutect2, varscan2
- FLG | c.10049C>G p.S3350* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as rs1557871489; called by muse, mutect2, varscan2
- HERC2 | c.7186G>A p.A2396T | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV99873993; called by muse, mutect2, varscan2
- MACF1 | c.14956C>T p.R4986W (on ENST00000372915; = p.R2919W on NM_012090.5) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as rs766474090; called by muse, mutect2, varscan2
- MOCS1 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs200517455, COSV57934931; called by muse, mutect2, varscan2
- MOV10L1 | c.3368T>G p.L1123W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53178576; called by muse, mutect2, varscan2
- PCDHA8 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as rs562900530; called by muse, mutect2
- PGAM5 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs376090046; called by mutect2, varscan2
- POLR1A | c.263A>T p.Y88F | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.657); catalogued as rs1360986972; called by muse, mutect2, varscan2
- PPP3CC | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV51500131; called by muse, mutect2, varscan2
- PTCH1 | c.956dup p.M319Ifs*118 | Frame Shift Ins (INS) | VAF 30/50 reads (60%) | catalogued as CI055020; called by mutect2, pindel, varscan2
- RGR | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs1343178443; called by muse, mutect2, varscan2
- RIF1 | c.6826-1G>C p.X2276_splice | Splice Site (SNP) | VAF 19/65 reads (29%) | catalogued as COSV54619592, COSV99690226; called by muse, mutect2, varscan2
- RMND5A | c.1160A>G p.K387R | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.76); PolyPhen benign (0.047); catalogued as rs202224251; called by muse, mutect2, varscan2
- SLC25A2 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV53404929; called by muse, mutect2, varscan2
- TP53 | c.318C>G p.S106R | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT tolerated (0.41); PolyPhen benign (0.149); catalogued as rs1555526581, CM013441, COSV52748282, COSV52919256, COSV53146850; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5C | c.1816G>A p.V606I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777197285, COSV71659131; called by muse, mutect2, varscan2
- USP31 | c.1862A>G p.H621R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs771953230; called by muse, mutect2, varscan2
- WDR19 | c.3628G>A p.A1210T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1286854859; called by muse, mutect2, varscan2
- ZFYVE9 | c.3548A>G p.Y1183C | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1170862297; called by muse, mutect2, varscan2
- ZNF347 | c.43A>G p.I15V | Missense Mutation (SNP) | VAF 77/112 reads (69%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs903621643; called by muse, mutect2, varscan2
- ADCK2 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 32/61 reads (52%) | called by muse, mutect2, varscan2
- AEBP1 | c.2524G>C p.G842R | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- AEBP2 | c.949A>G p.R317G | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AKAP1 | c.1014G>T p.L338F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.174); called by muse, mutect2
- AKAP1 | c.1016A>G p.D339G | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2
- AMER3 | c.2488C>T p.P830S | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.5); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- BRINP3 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.52); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- C9orf131 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CDH20 | c.1049C>A p.T350N | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- CLEC7A | c.735T>G p.F245L (on ENST00000304084 / NM_197947.3; = p.F199L on NM_022570.5) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL12A1 | c.6050C>G p.P2017R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHX35 | c.2dup p.M1? | Frame Shift Ins (INS) | VAF 70/168 reads (42%) | called by mutect2, pindel, varscan2
- DLC1 | c.1017G>T p.K339N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- DYNC2I1 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM189B | c.860A>T p.Y287F | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FAM189B | c.859T>A p.Y287N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FAT2 | c.7676C>T p.A2559V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FAT2 | c.7675G>T p.A2559S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FDPS | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.045); called by muse, mutect2
- GRHL1 | c.244del p.E82Rfs*18 | Frame Shift Del (DEL) | VAF 52/93 reads (56%) | called by mutect2, pindel, varscan2
- HDDC2 | c.312A>T p.E104D | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HYDIN | c.5889G>A p.W1963* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- ITPRID1 | c.1518T>A p.F506L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- LSM11 | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MT1M | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- NLRC4 | c.2728G>C p.V910L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NOBOX | c.612del p.K205Sfs*63 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- OR4S2 | c.96C>G p.F32L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OR5V1 | c.749T>A p.L250H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCNX1 | c.2263A>C p.N755H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PELI3 | c.389A>C p.Y130S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PHTF1 | c.1118G>T p.R373L | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PML | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PPIP5K1 | c.3974G>T p.C1325F (on ENST00000396923; = p.C1300F on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRUNE2 | c.5373A>C p.E1791D | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SEMA5A | c.2396A>C p.D799A | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- SGK1 | c.1102A>G p.I368V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SLC25A5 | c.715A>G p.M239V | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- SLC9A5 | c.1951A>T p.T651S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPAG8 | c.654A>T p.R218S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SPAG8 | c.653G>C p.R218T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STK11IP | c.2863G>C p.V955L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.104); called by muse, mutect2
- STK4 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STXBP5L | c.2566G>C p.G856R | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SYNRG | c.2552dup p.M851Ifs*3 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- TAF3 | c.2305C>A p.Q769K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TFIP11 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TIMP3 | c.602del p.P201Rfs*26 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- TLR8 | c.1129T>C p.Y377H (on ENST00000218032 / NM_138636.5; = p.Y395H on NM_016610.4) | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TM7SF3 | c.998A>T p.Y333F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRIP10 | c.1481C>T p.A494V (on ENST00000313244 / NM_001288962.2; = p.A438V on NM_004240.4) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TTN | c.55383A>G p.I18461M (on ENST00000591111; = p.I11037M on NM_003319.4) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- VPS54 | c.2251A>T p.I751F | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- WDR72 | c.2246G>C p.S749T | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF260 | c.560C>A p.T187N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- ZNF461 | c.499del p.I167Lfs*98 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | called by mutect2, pindel, varscan2
- ZNF484 | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF71 | c.1326G>T p.Q442H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- ANKRD11 | c.7683C>T p.S2561= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs781285799; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATF4 | c.60C>T p.F20= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV57478102, COSV57480890; called by muse, mutect2, varscan2
- CACNA1E | c.3885G>A p.V1295= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100704965, COSV62406811; called by muse, mutect2, varscan2
- CACNG8 | c.774G>A p.S258= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- CCDC69 | c.651G>A p.T217= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs369963539; called by muse, mutect2, varscan2
- FMO2 | c.39T>C p.S13= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs1297745958; called by muse, mutect2, varscan2
- IL1RL2 | c.360T>C p.T120= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- MCHR2 | c.402C>T p.A134= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV56004584; called by muse, mutect2, varscan2
- PCDHGB7 | c.192C>T p.R64= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV53900968; called by muse, mutect2, varscan2
- PLCH2 | c.2190C>T p.C730= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs777973464; called by muse, mutect2, varscan2
- POR | c.594C>T p.L198= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs782083065; called by muse, mutect2, varscan2
- PRDM9 | c.822C>T p.G274= | Silent (SNP) | VAF 16/105 reads (15%) | called by muse, mutect2, varscan2
- PRDM9 | c.1848C>A p.G616= | Silent (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- PSG1 | c.741C>T p.N247= | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as rs769102835, COSV54946457; called by muse, varscan2
- PTPN14 | c.1017C>T p.P339= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs138976528; called by muse, mutect2, varscan2
- SLC2A9 | c.576C>A p.I192= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV53331051, COSV99304538; called by muse, mutect2, varscan2
- SS18L1 | c.258C>T p.G86= | Silent (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- TBC1D9 | c.1434A>G p.K478= | Silent (SNP) | VAF 21/57 reads (37%) | called by muse, mutect2, varscan2
- TRGC1 | c.114C>T p.F38= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- UTRN | c.3384G>T p.A1128= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV62333445; called by muse, mutect2, varscan2
- CTBP1 | c.41-3165C>T | Intron (SNP) | VAF 13/40 reads (33%) | catalogued as rs749744584; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827800 C>A | 3'Flank (SNP) | VAF 30/37 reads (81%) | catalogued as COSV59423985; called by muse, mutect2, varscan2
